Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46P, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46P-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, left, upper lobe: 17.0 x 16.0 x 5.0 cm

tumor diameter: 6.0 cm

Diagnosis:

Adenocarcinoma mixed subtype (predominantly papillary, partially acinar, BAC)

pT2, pN0 (0/7), pMx, G2

1 CD-0-3
adenocarcinoma, w/ mixed subtypes
8255/3
Site: lung, upper lobe C34.1

Pathologist:

hw
9/24/12

hw
8/24/12

Source: NCI Genomic Data Commons file 0b57a750-826d-4fb1-b521-4033e57f6020 (TCGA-62-A46P.1520ADC4-F5A7-4412-B2E7-A26326EE0074.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).